CCDI case PBCEHB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/48c11035-0b69-4f63-aa4c-6b6c49afd264

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.7 years (5,004 days).

Biospecimens (2 samples)
- Sample 0DPUTI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPUTM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
